Surgical pathology report (de-identified scan), TCGA case TCGA-06-0137, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0137-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

06-0137-01R

Surgical Pathology Report

[REDACTED]

CLINICAL HISTORY

[REDACTED] with right parieto-occipital glioblastoma in [REDACTED]
[REDACTED] Currently, recurrence.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, biopsy
B: Brain, resection

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, right parieto-occipital, excision: Glioblastoma.
See comment.

COMMENT

The specimens are fragments of cerebrum containing a neoplastic proliferation of astrocytes with nuclear anaplasia, mitotic figures, microvascular proliferation and necrosis. There are zones of pseudosarcoma, and the neurons present are interpreted as entrapped.

[REDACTED]

PROCEDURES/ADDENDA

Interpretation

MIB-1 PROLIFERATION INDEX: 19%.

Results-Comments

IMMUNOHISTOCHEMISTRY: The GFAP depicts sparse glial fibrillogenesis by the tumor cells in the more cellular zones, a little more abundant in the looser areas. With the MIB-1, there is a proliferation index of about 19% in the more active areas.

[REDACTED]

[page 2 of 2]
=====

INTRA-OPERATIVE CONSULTATION

Brain, biopsy, touch prep and smears: Malignant tumor (c/w glioma).

[REDACTED]

GROSS DESCRIPTION

A. Received fresh, 2 fragments, 0.8 cm. across in aggregate. Semi firm, tannish-grey. In total, A1 and A2.

B. Received fresh, 2 fragments, 1.7 cm. across, in aggregate. Semi-firm, tannish-white. In total, B1 and B2.

[REDACTED]

ICD-9(s):

191.3 191.3

[REDACTED]

Histo Data

Part A: Brain. biopsy

[REDACTED]

Stain/Cnt	Block	Ordered	Comment
mGFAP-DA x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
MIB1-DA x 1	1	[REDACTED]	

Part B: Brain. resection

[REDACTED]

*** End of Report ***

Source: NCI Genomic Data Commons file 9158e5c3-7147-4a19-9377-341e863b7e50 (TCGA-06-0137.608435F3-0B6E-4191-B678-C023E8936906.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).